Surgical pathology report (de-identified scan), TCGA case TCGA-XP-A8T7, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Sao Paulo, specimen TCGA-XP-A8T7-01A (Primary Tumor).

ICD-O-3

Carcinoma, squamous cell NOS

Site: ^{CHF} Esophagus, middle third 8670/3
^{path} Esophagus, distal third C15.4
C15.5

Nature of material: Esophagus

Received on:

ANATOMOPATHOLOGIC RESULT

GW 1/28/14

MACROSCOPY

Received 2 vials, identified as follows:

- 1) Esophagus: surgical specimen consisted of the distal esophagus and gastric stump. The esophagus is open, measures 10 cm long and 2.5 cm in diameter, with brown outer surface, with congested vessels. In organ light we note exophytic, crispy and white lesion, measuring 5 x 3 cm in area, lying 4.5 cm from the proximal margin and 1.5 cm from the cardia. After cutting, it is clear that the lesion fills the entire thickness of the esophagus. The gastric stump measures 4.5 x 3.5 x 0.4 cm, with brown-gray, rough and opaque serous, and wrinkled mucosa, of usual pattern. Came with brownish tubular fragment, measuring 2.2 cm long and 1.2 cm in diameter. 8 lymph nodes are dissected, with the largest measuring 1.3 cm and smaller, 0.3 cm.
- 2) Gall bladder: previously opened, measuring 8.5 cm long, 3.5 cm diameter and 0.4 cm wall thickness. The serosa is grayish-brown, smooth and bright, with congested vessels. The mucosa is greenish-brown, with areas alternating between velvety and smooth patterns. The cystic duct stump measures 1cm in diameter. Are observed tiny cholesterol stones.

MICROSCOPY

Description dispensable.

DIAGNOSTIC

Product of subtotal esophagectomy and cholecystectomy:

Moderately differentiated squamous cell carcinoma

- Neoplasm measuring 5 x 3cm.
- Macroscopic form: vegetating.
- Infiltration level: muscle layer.
- Growing Form: infiltrative.
- Stromal reaction: moderate inflammatory infiltrate and moderate desmoplasia.
- Vascular infiltration: absent.
- Perineural infiltration: absent.
- Clear margins, lying 4.5 cm from the proximal margin.
- Lymph nodes: no metastasis evaluated in 9 (0/9).
- Pathological Staging: pT2 pN0.
- Chronic cholecystitis, calculous.

PARTICIPANTS OF APPRAISAL REPORT

- ISSUER

Criteria	GW 11/8/13	Yes	No
Diagnostic Discrepancy			
Qual/Ameliorous Primary Site			
Case is Single			

11/28/13

Source: NCI Genomic Data Commons file fe7b038c-3187-4915-99a2-73e779fc54e8 (TCGA-XP-A8T7.170AAED8-3B4E-46C1-AF9D-956DF8D2E438.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).